Somatic mutation profile of tumor specimen MP2PRT-PATGRT-TMP1-A (aliquot MP2PRT-PATGRT-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PATGRT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,192 days).
Specimen MP2PRT-PATGRT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 777bf686-d832-4942-a0b8-be5267505571.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGRT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGRT-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/031544ab-2ba8-4a4e-b828-e090e981db54

The open-access MAF lists 80 somatic variants for this specimen: 60 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 19, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 60/320 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 43/306 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- PTPN11 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 31/226 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs121918455, CM021135, CM044252, COSV61006976, COSV61014185; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASTL | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 141/394 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1430983062; called by muse, mutect2, varscan2
- CECR2 | c.1802G>A p.R601H (on ENST00000342247 / NM_001290047.2; = p.R418H on NM_001290046.1) | Missense Mutation (SNP) | VAF 117/541 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs565809706; called by muse, mutect2, varscan2
- DDX52 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 186/599 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as rs770680305; called by muse, mutect2, varscan2
- DENND2C | c.2576G>A p.R859Q (on ENST00000393274 / NM_001256404.2; = p.R802Q on NM_198459.4) | Missense Mutation (SNP) | VAF 54/324 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs754052667; called by muse, mutect2, varscan2
- EPPK1 | c.4942G>A p.A1648T | Missense Mutation (SNP) | VAF 439/845 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370754670; called by muse, mutect2
- FAT1 | c.3047G>A p.C1016Y | Missense Mutation (SNP) | VAF 146/479 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs746500278; called by muse, mutect2, varscan2
- FLNC | c.2566C>T p.P856S | Missense Mutation (SNP) | VAF 109/323 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1259966971; called by muse, mutect2, varscan2
- GPR32 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs747829098, COSV54514925, COSV54515776; called by muse, mutect2, varscan2
- GRAMD4 | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 89/243 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as rs1427796872; called by muse, mutect2, varscan2
- KCNH4 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 69/629 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs201966056; called by muse, mutect2, varscan2
- KDR | c.2497C>T p.R833W | Missense Mutation (SNP) | VAF 64/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224362892, COSV55764173; called by muse, mutect2, varscan2
- MROH7 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 158/402 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs1233105795, COSV59873899; called by muse, mutect2, varscan2
- MXRA5 | c.5747G>A p.R1916Q | Missense Mutation (SNP) | VAF 143/547 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs769800166; called by muse, mutect2, varscan2
- MYH13 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 100/359 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as rs759137231; called by muse, mutect2, varscan2
- OR1N2 | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs267602123, COSV101031372; called by muse, mutect2
- PIGG | c.1490C>T p.S497L (on ENST00000453061 / NM_001127178.3; = p.S489L on NM_017733.4) | Missense Mutation (SNP) | VAF 116/498 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs755547556, COSV56316311; called by muse, mutect2, varscan2
- PTPRF | c.3077C>T p.T1026M | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752333602; called by muse, mutect2, varscan2
- PTPRH | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs774328048; called by muse, mutect2, varscan2
- PXDNL | c.3304C>T p.R1102W | Missense Mutation (SNP) | VAF 124/509 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62485418; called by muse, mutect2, varscan2
- RALYL | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 40/446 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs766785304, COSV72819337; called by muse, mutect2
- STEAP4 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs774129138, COSV57329435; called by muse, mutect2, varscan2
- TMEM179 | c.93C>G p.N31K | Missense Mutation (SNP) | VAF 200/738 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58794998; called by muse, mutect2, varscan2
- TTN | c.38716G>A p.E12906K (on ENST00000591111; = p.E5482K on NM_003319.4) | Missense Mutation (SNP) | VAF 143/368 reads (39%) | PolyPhen benign (0.077); catalogued as rs761539202, COSV59933910; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT2B4 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 119/341 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.08); catalogued as rs767837637, COSV59316341, COSV59318216; called by muse, mutect2, varscan2
- UGT8 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 135/493 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs369373697; called by muse, mutect2, varscan2
- ZFHX4 | c.4456G>A p.E1486K | Missense Mutation (SNP) | VAF 255/507 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs755334619, COSV99267910; called by muse, mutect2, varscan2
- ZNF335 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 130/326 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as rs760410435; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF560 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 108/316 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs149138221, COSV56867070; called by muse, mutect2, varscan2
- AL136295.1 | c.1334G>A p.W445* | Nonsense Mutation (SNP) | VAF 194/672 reads (29%) | called by muse, mutect2, varscan2
- C9orf43 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 106/251 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CBLN1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 166/461 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CFAP92 | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 165/415 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CHD8 | c.7376C>A p.S2459Y (on ENST00000646647 / NM_001170629.2; = p.S2180Y on NM_020920.4) | Missense Mutation (SNP) | VAF 76/620 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- COL5A3 | c.4565C>T p.S1522L | Missense Mutation (SNP) | VAF 188/481 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CYP1B1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 129/599 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DCAF4 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 106/415 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHRS9 | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 107/306 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH3 | c.5541G>T p.R1847S | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENPEP | c.2437G>T p.A813S | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FGD5 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 170/414 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HOXC9 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 185/496 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGF2R | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 90/443 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MAP4K1 | c.211_212insTCCAGGG p.H71Lfs*47 | Frame Shift Ins (INS) | VAF 64/267 reads (24%) | called by mutect2, pindel*, varscan2*
- MYOM2 | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 234/419 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NR2F1 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 175/448 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NRG2 | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 113/300 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- PAPSS1 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 129/512 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PDZD4 | c.125A>T p.K42M | Missense Mutation (SNP) | VAF 154/593 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PRUNE2 | c.3923G>A p.G1308E | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RBP3 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 61/386 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHISA9 | c.1104del p.F368Lfs*55 | Frame Shift Del (DEL) | VAF 96/571 reads (17%) | called by pindel, varscan2
- SLC38A8 | c.975G>A p.W325* | Nonsense Mutation (SNP) | VAF 166/431 reads (39%) | called by muse, mutect2, varscan2
- SLCO1B3 | c.646G>C p.G216R | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- SPATA31A3 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 114/299 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SYCN | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 104/604 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- TPR | c.3495A>C p.K1165N | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13C | c.10886G>A p.G3629E (on ENST00000644861 / NM_020821.3; = p.G3586E on NM_017684.5) | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF11 | c.2970G>A p.E990= | Silent (SNP) | VAF 88/254 reads (35%) | catalogued as rs765677808, COSV59352243; called by muse, mutect2, varscan2
- CAMSAP3 | c.2034G>A p.R678= | Silent (SNP) | VAF 213/507 reads (42%) | catalogued as rs1305034941; called by muse, mutect2, varscan2
- CFAP92 | c.1161C>T p.L387= | Silent (SNP) | VAF 171/422 reads (41%) | catalogued as rs775573362; called by muse, mutect2, varscan2
- CSNKA2IP | c.1005G>A p.T335= | Silent (SNP) | VAF 90/264 reads (34%) | catalogued as rs1306954367; called by muse, mutect2, varscan2
- DDR2 | c.2508G>A p.T836= | Silent (SNP) | VAF 132/334 reads (40%) | catalogued as rs764563713; ClinVar: likely benign; called by muse, varscan2
- DIO3 | c.453C>T p.I151= | Silent (SNP) | VAF 179/607 reads (29%) | catalogued as rs1421934282; called by muse, mutect2, varscan2
- DNAH8 | c.12835C>T p.L4279= | Silent (SNP) | VAF 66/177 reads (37%) | called by muse, mutect2, varscan2
- GABPA | c.642A>G p.T214= | Silent (SNP) | VAF 93/541 reads (17%) | catalogued as rs767605038; called by muse, mutect2, varscan2
- GRIK2 | c.1824G>A p.L608= | Silent (SNP) | VAF 93/314 reads (30%) | called by muse, varscan2
- HEPH | c.1620C>T p.F540= (on ENST00000343002; = p.F273= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 204/705 reads (29%) | catalogued as rs766933299, COSV100293947; called by muse, mutect2, varscan2
- HOXC9 | c.96G>A p.G32= | Silent (SNP) | VAF 186/495 reads (38%) | catalogued as COSV100327649; called by muse, mutect2, varscan2
- MUC12 | c.4194C>T p.L1398= (on ENST00000379442; = p.L1255= on NM_001164462.1) | Silent (SNP) | VAF 165/511 reads (32%) | called by muse, mutect2, varscan2
- NAV2 | c.4149G>A p.V1383= (on ENST00000396087 / NM_001244963.2; = p.V1360= on NM_145117.5) | Silent (SNP) | VAF 187/459 reads (41%) | catalogued as rs755938187; called by muse, varscan2
- OR4C5 | c.399C>T p.I133= | Silent (SNP) | VAF 161/398 reads (40%) | catalogued as rs1409379686; called by muse, mutect2, varscan2
- PDE2A | c.1857C>T p.I619= | Silent (SNP) | VAF 94/241 reads (39%) | called by muse, mutect2, varscan2
- PRKG2 | c.771A>T p.L257= | Silent (SNP) | VAF 52/217 reads (24%) | called by muse, mutect2, varscan2
- PXDNL | c.3303C>T p.L1101= | Silent (SNP) | VAF 126/511 reads (25%) | catalogued as rs774724051, COSV62489971; called by muse, mutect2, varscan2
- WDR62 | c.1497G>A p.Q499= | Silent (SNP) | VAF 134/356 reads (38%) | called by muse, mutect2, varscan2
- WNT6 | c.1077G>A p.K359= | Silent (SNP) | VAF 151/434 reads (35%) | called by muse, mutect2, varscan2
- FAM9B | c.-89-26C>T | Intron (SNP) | VAF 135/511 reads (26%) | called by muse, mutect2, varscan2
